Surgical pathology report (de-identified scan), TCGA case TCGA-CN-6017, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-CN-6017-01A (Primary Tumor).

[page 1 of 5]
Report Type Pathology Report

Date of Event [REDACTED]

Sex [REDACTED]

Authored by [REDACTED]

Hosp/Group [REDACTED]

Record Status FINAL

FINAL DIAGNOSIS:

PART 1: BASE OF TONGUE, LEFT, EXCISION

NO TUMOR PRESENT.

PART 2: TONGUE, LEFT, HEMIGLOSSECTOMY

A. INVASIVE SQUAMOUS CELL CARCINOMA, MODERATELY DIFFERENTIATED (4.7 CM), KERATINIZING.

B. PERINEURAL INVASION PRESENT.

C. SEVERE DYSPLASIA/CARCINOMA IN SITU AT LATERAL MARGIN, FINAL MARGINS FREE OF INVASIVE CARCINOMA (see also parts 3, and 7).

D. PATHOLOGIC STAGE: pT3 N2b.

PART 3: ADDITIONAL DEEP MARGIN, EXCISION

NO TUMOR PRESENT.

PART 4: LYMPH NODES, LEFT NECK LEVEL 2, SELECTIVE DISSECTION

A. METASTATIC SQUAMOUS CELL CARCINOMA IN ONE OF THIRTEEN LYMPH NODES (1/13), 2.1 CM, LEVEL 2B, WITH EXTRACAPSULAR SPREAD.

B. UNREMARKABLE PAROTID TISSUE.

PART 5: LYMPH NODES, LEFT NECK LEVEL 3-4, SELECTIVE DISSECTION

METASTATIC SQUAMOUS CELL CARCINOMA IN TWO OF NINE LYMPH NODES (2/9), 0.4 CM, LEVEL 3, NO EXTRACAPSULAR SPREAD.

PART 6: LYMPH NODE, LEFT NECK LEVEL 1A AND B, SELECTIVE DISSECTION

A. EIGHT LYMPH NODES, NO TUMOR PRESENT (0/8).

B. UNREMARKABLE SUBMANDIBULAR GLAND.

PART 7: ADDITIONAL POSTERIOR MARGIN, EXCISION

NO TUMOR PRESENT.

[REDACTED]

My signature is attestation that I have personally reviewed the submitted material(s) and the final diagnosis reflects that evaluation.

GROSS DESCRIPTION:

The specimen is received in seven parts.

Part 1 is received fresh for intraoperative consultation labeled with the patient's name, initials xxx and "left base of tongue". It consists of two fragments of tan-brown, soft tissue measuring 0.6 x 0.5 x 0.4 cm and 0.5 x 0.3 x 0.2 cm. The frozen tissue is submitted for permanent section in cassette 1AFS.

Part 2 is received fresh labeled with the patient's name, initials xxx and "left hemiglossectomy, stitch is anterior". It consists of a 5.5 x 3.6 x 2.5 cm apparent hemiglossectomy. A stitch marks the anterior aspect. On cut section a white, irregular, unencapsulated poorly defined tumor, measuring 4.7

[page 2 of 5]
x 3.4 x 2.5 cm, is seen within the tongue. Digital photographs are taken.

Tissue is collected for banking.

INK CODE:

Black posterior (area surgically marked)

Yellow anterior margin

Orange overlying green lateral margin

Green medial

Red site of tissue banking

SECTION CODE:

1AFS - Posterior deep (shave) - surgically inked area

2BFS mid dorsomedial mucosa (perpendicular)

2CFS mid dorsomedial soft tissue (perpendicular)

2D anterior margin

2E lateral margin

2F thru 2J representative sections of tumor.

Part 3 is received fresh labeled with the patient's name, initials xxx and

"additional deep margin". It consists of a tan-brown portion of soft tissue.

The frozen tissue is submitted for permanent sections in cassette 3AFS. The remainder of the tissue is submitted in cassette 3B.

Part 4 is received fresh labeled with the patient's name, initials xxx and

"left neck level 2, long stitch at 2A, short is 2B". It consists of an 8.7 x 4.5 x 1.5 cm portion of yellow adipose tissue and tan-pink fibrous tissue. A long stitch marks level 2A and a short stitch marks level 2B. A separate fragment of adipose tissue measuring 2.6 x 0.7 x 0.5 cm is also included. The separate fragment contains two possible lymph nodes, measuring 0.6 x 0.6 x 0.6 cm and 1.0 x 0.6 x 0.6 cm. Level 2A contains six possible lymph nodes measuring 0.5 x 0.4 x 0.2 cm to 2.0 x 1.7 x 1.1 cm. Level 2B contains eleven possible lymph nodes measuring 0.3 x 0.2 x 0.2 cm to 1.7 x 1.1 x 0.4 cm and an enlarged lymph node measuring 3.0 x 1.8 x 1.4 cm.

SECTION CODE:

4A two possible lymph nodes from separate segment of tissue

4B six lymph nodes from level 2A

4C thru 4D enlarged lymph node, level 2B, bisected

4E one lymph node from level 2B, bisected

4F two lymph nodes from level 2B

4G two lymph nodes from level 2B

4H three lymph nodes from level 2B

4I four lymph nodes from level 2B.

Part 5 is received fresh labeled with the patient's name, initials xxx and

"left neck levels 3 and 4". It consists of a 4.0 x 3.7 x 0.6 cm unoriented

portion of yellow adipose tissue and tan-pink fibrous tissue. Level 3 contains two possible lymph nodes measuring up to 1.6 x 1.5 x 0.5 cm. Level 4 contains eight possible lymph nodes measuring between 0.1 x 0.1 x 0.1 cm and 0.8 x 0.6 x 0.3 cm.

SECTION CODE:

5A one lymph node from level 3, bisected

5B - one lymph node from level 3, bisected

5C three lymph nodes from level 4

5D five lymph nodes from level 4.

Part 6 is received fresh labeled with the patient's name, initials xxx and

"left neck level 1A and B". It consists of an 11.0 x 4.9 x 1.9 portion of unoriented yellow adipose tissue and tan-pink fibrous tissue containing a 4.8 x 4.5 x 1.8 cm submandibular gland and eight possible lymph nodes ranging from 0.3 x 0.2 x 0.2 cm to 1.0 x 0.9 x 0.5 cm.

SECTION CODE:

6A four possible lymph nodes from level 1A

[page 3 of 5]
6B four possible lymph nodes from level 1A
6C one possible lymph node, bisected from level 1B
6D three possible lymph nodes from level 1B
6E representative section of submandibular gland from level 1B.
Part 7 is received fresh for intraoperative consultation labeled with the patient's name, initials xxx and "additional posterior margin, stitch is anterior, ink on true margin". It consists of three fragments of brown, soft tissue measuring 2.5 x 1.5 x 1.3 cm, 0.5 x 0.5 x 0.2 cm, and 2.4 x 2.1 x 0.4 cm. The first two fragments of frozen tissue are submitted for permanent section in cassette 7AFS. The third fragment of frozen tissue is submitted for permanent section in cassette 7BFS.

INK CODE:

Anterior green

Posterior black.

Dictated by: [REDACTED]

INTRAOPERATIVE CONSULTATION:

1A: LEFT BASE OF TONGUE (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

2A: POSTERIOR DEEP (SHAVE) MARGIN SURGICALLY INKED AREA (frozen section)

A. MALIGNANT.

B. MICROSCOPIC FOCI OF SQUAMOUS CELL CARCINOMA ([REDACTED]).

2B: MID DORSOMEDIAL MARGIN (PERPENDICULAR) (frozen section)

A. MALIGNANT.

B. SQUAMOUS CELL CARCINOMA AT SOFT TISSUE MARGIN ([REDACTED]).

2C: MID DORSOMEDIAL SOFT TISSUE (PERPENDICULAR) (frozen section)

A. MALIGNANT.

B. SQUAMOUS CELL CARCINOMA <0.1 CM FROM SOFT TISSUE MARGIN ([REDACTED]).

3A: ADDITIONAL DEEP MARGIN (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT.

C. DETACHED DEGENERATED CAUTERIZED EPITHELIUM WITH ACUTE MUCOSITIS ([REDACTED]).

7A: ADDITIONAL POSTERIOR MARGIN (POSTERIOR) (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

7B: ADDITIONAL POSTERIOR MARGIN (ANTERIOR) (frozen section)

A. BENIGN.

B. NO TUMOR PRESENT ([REDACTED]).

MICROSCOPIC:

Microscopic examination substantiates the above diagnosis.

The following statement applies to all immunohistochemistry, In situ Hybridization Assays (ISH & FISH), Molecular Anatomic Pathology, and Immunofluorescent Testing:

The testing was developed and its performance characteristics determined by the [REDACTED] Department of Pathology, as required by the CLIA [REDACTED] regulations. The testing has not been cleared or approved for the specific use by the U.S. Food and Drug Administration, but the FDA has determined such approval is not necessary for clinical use. Tissue fixation

[page 4 of 5]
ranges from a minimum of [REDACTED] a maximum of [REDACTED] hours.

This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] ("CLIA") as qualified to perform high-complexity clinical testing. Pursuant to the requirements of CLIA, ASR's used in this laboratory have been established and verified for accuracy and precision. Additional information about this type of test is available upon request.

CASE SYNOPSIS:

SYNOPTIC DATA - PRIMARY UPPER AERODIGESTIVE TRACT AND SALIVARY GLAND

TUMORS

SPECIMEN TYPE: Resection: hemiglossectomy

TUMOR SITE: Oral Cavity

TUMOR SIZE: Greatest dimension: 4.7 cm

Additional dimensions: 3.4 x 2.5 cm

HISTOLOGIC TYPE: Squamous cell carcinoma, conventional

HISTOLOGIC GRADE: G2

PRIMARY TUMOR (pT): pT3

REGIONAL LYMPH NODES (pN): pN2b

Number of regional lymph nodes examined: 30

Number of regional lymph nodes involved: 3

Extra-capsular extension of nodal tumor: Present

DISTANT METASTASIS (pM): pMX

MARGINS: Carcinoma in situ present

VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION (V/L):

Present

PERINEURAL INVASION: Absent

ADDITIONAL PATHOLOGIC FINDINGS: Inflammation (type): acute and chronic

PATIENT HISTORY:

CHIEF COMPLAINT/ PRE-OP/ POST-OP DIAGNOSIS: Malignant neoplasm mss.

PROCEDURE: Neck dissection, partial glossectomy.

BIOHAZARD: No.

SPECIFIC CLINICAL QUESTION: Not answered.

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMORADIATION THERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

CYTOGENETIC TESTS: Not answered.

HISTO TISSUE SUMMARY/SLIDES REVIEWED:

Part 1: Left Base of Tongue

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 AFS

Part 2: Left Hemiglossectomy

Taken: [REDACTED]

Stain/cnt Block

H&E x 1 D

RHHE Lev ___ x 1 E

RHHE Lev ___ x 1 E

RHHE Lev ___ x 1 E

RHHE Lev ___ x 1 E

RHHE Lev ___ x 1 E

H&E x 1 E

H&E x 1 F

[page 5 of 5]
H&E Recut x 1 G

IEGFR x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

IBNKNC x 1 G

H&E x 1 G

HPV x 1 G

P16 x 1 G

V-EGFR x 1 G

H&E x 1 H

H&E x 1 I

H&E x 1 J

H&E x 1 AFS

H&E x 1 [REDACTED]

H&E x 1 [REDACTED]

Part 3: Additional Deep Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 B

H&E x 1 AFS

Part 4: Left Neck Level 2

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

H&E x 1 F

H&E x 1 G

H&E x 1 H

H&E x 1 I

Part 5: Left Neck Level 3-4

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

Part 6: Left Neck Level 1A&B

Taken: [REDACTED] [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 A

H&E x 1 B

H&E x 1 C

H&E x 1 D

H&E x 1 E

Part 7: Additional Posterior Margin

Taken: [REDACTED] [REDACTED]

Stain/cnt Block

H&E x 1 AFS

H&E x 1 BFS

[REDACTED]

Source: NCI Genomic Data Commons file 49245e58-0355-4560-b05b-952d9eebbf83 (TCGA-CN-6017.0F441278-42CE-4DF9-9C5A-BCBE27D8A78F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).